Somatic mutation profile of tumor specimen MMRF_2648_1_BM_CD138pos (aliquot MMRF_2648_1_BM_CD138pos_T1_KHS5U_L13432) from MMRF case MMRF_2648, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.1 years (23,405 days).
Specimen MMRF_2648_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1913ec91-a2bc-4d28-b8b9-9ddbf645587e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2648_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2648_1_PB_WBC_C2_KHS5U_L13420; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/478d0c98-b05f-4205-8ccd-f6ed18afb216

The open-access MAF lists 122 somatic variants for this specimen: 55 protein-altering or splice-affecting, 12 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, 3'UTR 28, Intron 16, Silent 12, 5'UTR 5, 5'Flank 3, RNA 2, Splice Region 2, Frame Shift Del 2, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HPS1 | c.962del p.G321Afs*10 | Frame Shift Del (DEL) | VAF 31/270 reads (11%) | catalogued as rs281865081, CD982690; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACTN3 | c.2146G>A p.D716N | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.716); catalogued as rs191891560; called by muse, mutect2, varscan2
- ADAMTS5 | c.1360A>G p.K454E | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as rs917456224; called by muse, mutect2, varscan2
- CCDC113 | c.701A>G p.E234G | Missense Mutation (SNP) | VAF 43/237 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs768427983; called by muse, mutect2, varscan2
- CORO2B | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55955837; called by muse, mutect2, varscan2
- EGR1 | c.102G>C p.K34N | Missense Mutation (SNP) | VAF 94/370 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.475); catalogued as rs368477832, COSV53518271; called by muse, varscan2
- EGR1 | c.245G>C p.S82T | Missense Mutation (SNP) | VAF 74/207 reads (36%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.037); catalogued as rs898320714; called by muse, varscan2
- FARP2 | c.2351A>C p.Y784S | Missense Mutation (SNP) | VAF 32/202 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50870407; called by muse, varscan2
- HADHB | c.1315A>G p.M439V | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs1392529342; called by muse, mutect2, varscan2
- HSPG2 | c.6010C>T p.R2004C | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as rs777591903, COSV101020332, COSV65975083; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHV3-33 | c.136T>A p.F46I | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.436); catalogued as rs746660718; called by muse, varscan2
- IGHV4-34 | c.320A>G p.K107R | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs768900759; called by muse, mutect2, varscan2
- IGLV3-1 | c.295A>G p.M99V | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs61731681; called by muse, varscan2
- IGLV4-3 | c.196A>G p.I66V | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs529123510; called by muse, varscan2
- KCNH2 | c.121G>T p.V41F | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as rs199472835, CM097271; ClinVar: not provided; called by muse, mutect2, varscan2
- KIF9 | c.1864C>T p.R622W (on ENST00000265529 / NM_001377474.1; = p.R557W on NM_022342.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs747650428; called by muse, varscan2
- MGAT5B | c.69-2A>G p.X23_splice | Splice Site (SNP) | VAF 32/197 reads (16%) | catalogued as rs1448790444; called by muse, mutect2, varscan2
- OPTC | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 30/285 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as rs868084079, COSV65867246; called by muse, mutect2, varscan2
- OVCH2 | c.784G>A p.G262S | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1399016160; called by muse, mutect2, varscan2
- PROKR2 | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.403); catalogued as rs368732206, CM1312721; called by muse, mutect2, varscan2
- STARD13 | c.74A>T p.E25V | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); catalogued as rs1317250594; called by muse, mutect2, varscan2
- THADA | c.4741C>G p.P1581A | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0.006); catalogued as COSV57694866; called by muse, mutect2, varscan2
- ZC3H11A | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0.048); catalogued as rs1192984971; called by muse, mutect2, varscan2
- ZNF580 | c.326G>A p.S109N | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs754255299; called by muse, mutect2, varscan2
- APOB | c.4987A>C p.S1663R | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP131 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL17A1 | c.448T>C p.S150P | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- DPP6 | c.2510G>A p.R837Q (on ENST00000377770 / NM_001364500.2; = p.R775Q on NM_001936.5) | Missense Mutation (SNP) | VAF 58/360 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EBF2 | c.1585T>A p.S529T | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FBXL17 | c.530A>C p.Q177P | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- FBXO28 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLNC | c.2899A>T p.S967C | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- GRID1 | c.2621A>G p.E874G | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- IGHD | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- IGLV3-1 | c.37T>G p.Y13D | Missense Mutation (SNP) | VAF 44/264 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- IGLV4-3 | c.160T>A p.W54R | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- KDM3B | c.151A>C p.T51P | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIAA1671 | c.1533G>T p.L511F | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- LRRTM3 | c.260T>C p.L87P | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGI2 | c.3279G>T p.Q1093H | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MSR1 | c.340T>C p.F114L | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAGS | c.1340T>A p.V447E | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCKAP5 | c.1301A>G p.E434G | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- NKX1-1 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- OAT | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RELN | c.3006T>G p.T1002= | Splice Region (SNP) | VAF 34/239 reads (14%) | called by muse, mutect2, varscan2
- RRAS2 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- SACS | c.4621T>G p.L1541V | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- SDK2 | c.1516A>T p.S506C | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- SIK2 | c.515T>C p.L172P | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM45A | c.294G>A p.M98I | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- TOM1L2 | c.904T>G p.Y302D (on ENST00000379504 / NM_001350333.2; = p.Y252D on NM_001033551.3) | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TUBG1 | c.399+7G>A | Splice Region (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
- WDFY2 | c.755A>C p.Q252P | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- WFDC3 | c.52_53del p.L18Gfs*19 | Frame Shift Del (DEL) | VAF 26/230 reads (11%) | called by pindel, varscan2
- CASR | c.603C>T p.I201= | Silent (SNP) | VAF 18/144 reads (13%) | catalogued as COSV56134110; called by muse, mutect2, varscan2
- CHRNB2 | c.996G>A p.A332= | Silent (SNP) | VAF 45/250 reads (18%) | catalogued as rs762184252; called by muse, mutect2, varscan2
- FAM9B | c.414G>A p.Q138= | Silent (SNP) | VAF 28/170 reads (16%) | called by muse, mutect2, varscan2
- GET3 | c.676C>T p.L226= | Silent (SNP) | VAF 11/108 reads (10%) | called by muse, mutect2, varscan2
- GJA8 | c.249C>T p.I83= | Silent (SNP) | VAF 52/300 reads (17%) | called by muse, mutect2, varscan2
- IGLV4-60 | c.204G>A p.L68= | Silent (SNP) | VAF 45/267 reads (17%) | catalogued as rs554418977, COSV101135214, COSV66503697, COSV66503734; called by muse, mutect2, varscan2
- POU4F3 | c.171C>T p.A57= | Silent (SNP) | VAF 41/322 reads (13%) | called by muse, mutect2, varscan2
- PTPN14 | c.2478G>A p.K826= | Silent (SNP) | VAF 45/213 reads (21%) | called by muse, mutect2, varscan2
- PTPRG | c.813G>A p.R271= | Silent (SNP) | VAF 20/103 reads (19%) | called by muse, mutect2, varscan2
- SPTSSB | c.228T>C p.N76= | Silent (SNP) | VAF 35/375 reads (9%) | catalogued as rs137885746; called by muse, mutect2
- TBCC | c.405G>A p.K135= | Silent (SNP) | VAF 21/100 reads (21%) | called by muse, mutect2, varscan2
- ZNF730 | c.627C>T p.A209= | Silent (SNP) | VAF 8/198 reads (4%) | called by muse, mutect2
- AC022031.2 | n.156+67587C>T | Intron (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499644 G>C | 5'Flank (SNP) | VAF 29/167 reads (17%) | called by muse, mutect2, varscan2
- ATP2B4 | c.*3260C>T | 3'UTR (SNP) | VAF 25/126 reads (20%) | called by muse, mutect2, varscan2
- ATP8B4 | c.2142-693A>G | Intron (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2, varscan2
- C2orf91 | n.1549C>G | RNA (SNP) | VAF 20/120 reads (17%) | called by muse, mutect2, varscan2
- CDK2 | c.*497T>G | 3'UTR (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- CUL4B | chrX:120524695 del AAC | 3'Flank (DEL) | VAF 20/106 reads (19%) | catalogued as rs1364043002; called by pindel, varscan2
- ENAH | c.*4500G>A | 3'UTR (SNP) | VAF 16/129 reads (12%) | called by muse, mutect2, varscan2
- ESRP2 | c.*616T>A | 3'UTR (SNP) | VAF 22/156 reads (14%) | called by muse, mutect2, varscan2
- FAM155B | c.*478G>T | 3'UTR (SNP) | VAF 56/322 reads (17%) | called by muse, mutect2, varscan2
- FAM240C | c.*50_*80del | 3'UTR (DEL) | VAF 40/277 reads (14%) | called by mutect2, pindel
- FSIP2 | chr2:185738605 A>G | 5'Flank (SNP) | VAF 22/137 reads (16%) | called by muse, mutect2, varscan2
- FSTL5 | c.*1500T>G | 3'UTR (SNP) | VAF 20/82 reads (24%) | called by muse, mutect2, varscan2
- GDF3 | c.*81G>T | 3'UTR (SNP) | VAF 40/442 reads (9%) | called by muse, mutect2
- GINS4 | c.-154A>C | 5'UTR (SNP) | VAF 18/183 reads (10%) | called by muse, mutect2, varscan2
- GPR39 | c.-102C>T | 5'UTR (SNP) | VAF 14/142 reads (10%) | catalogued as rs968674377; called by muse, mutect2, varscan2
- GRAMD2A | c.42-58G>C | Intron (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- HEG1 | c.*3096A>T | 3'UTR (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- ITGB2 | c.58+11T>A | Intron (SNP) | VAF 29/197 reads (15%) | called by muse, mutect2, varscan2
- JUP | c.*93G>T | 3'UTR (SNP) | VAF 49/247 reads (20%) | called by muse, mutect2, varscan2
- KLHL1 | c.-73G>A | 5'UTR (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- LAMP2 | c.1093+2810C>T | Intron (SNP) | VAF 20/103 reads (19%) | called by muse, mutect2, varscan2
- LAX1 | c.-195T>G | 5'UTR (SNP) | VAF 45/222 reads (20%) | called by muse, mutect2, varscan2
- LYPD6 | c.*1060G>A | 3'UTR (SNP) | VAF 13/90 reads (14%) | catalogued as rs757413963; called by muse, mutect2, varscan2
- MIR522 | n.27A>G | RNA (SNP) | VAF 35/234 reads (15%) | called by muse, mutect2, varscan2
- MTAP | c.813+3322G>C | Intron (SNP) | VAF 14/95 reads (15%) | called by muse, mutect2, varscan2
- NPAS2 | c.1393-34A>G | Intron (SNP) | VAF 35/210 reads (17%) | called by muse, mutect2, varscan2
- PCDH17 | c.*310A>G | 3'UTR (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2, varscan2
- PTPRE | c.1388-70G>A | Intron (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- RAP2B | c.*1879dup | 3'UTR (INS) | VAF 10/88 reads (11%) | called by mutect2, pindel, varscan2
- RNF126 | c.135-84C>T | Intron (SNP) | VAF 26/75 reads (35%) | catalogued as rs980355109; called by muse, mutect2, varscan2
- RPRD1B | c.*2199A>G | 3'UTR (SNP) | VAF 17/79 reads (22%) | catalogued as rs1329484386; called by muse, mutect2, varscan2
- RRP7A | c.*2596T>C | 3'UTR (SNP) | VAF 27/159 reads (17%) | called by muse, mutect2, varscan2
- SCML2 | c.*1036G>A | 3'UTR (SNP) | VAF 9/136 reads (7%) | called by muse, mutect2
- SF1 | c.*738T>A | 3'UTR (SNP) | VAF 20/177 reads (11%) | catalogued as rs1051519680; called by muse, mutect2, varscan2
- SHISA9 | c.564-6931A>G | Intron (SNP) | VAF 16/117 reads (14%) | catalogued as rs1002988286; called by muse, mutect2, varscan2
- SLC2A13 | c.-265C>T | 5'UTR (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- SLC34A2 | c.*316T>C | 3'UTR (SNP) | VAF 20/129 reads (16%) | called by muse, mutect2, varscan2
- SLC6A20 | c.*2826C>T | 3'UTR (SNP) | VAF 12/127 reads (9%) | called by muse, mutect2
- SLTM | c.*578A>C | 3'UTR (SNP) | VAF 11/100 reads (11%) | called by muse, mutect2, varscan2
- SPATA13 | c.*2554A>G | 3'UTR (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- SPRY2 | c.*543C>T | 3'UTR (SNP) | VAF 12/77 reads (16%) | called by muse, mutect2, varscan2
- SRSF10 | c.*3374A>G | 3'UTR (SNP) | VAF 56/418 reads (13%) | called by muse, varscan2
- SRSF10 | c.*3302A>C | 3'UTR (SNP) | VAF 66/469 reads (14%) | called by muse, varscan2
- TIMP2 | c.*1646C>T | 3'UTR (SNP) | VAF 23/155 reads (15%) | called by muse, mutect2, varscan2
- TLN2 | c.*1448T>C | 3'UTR (SNP) | VAF 47/144 reads (33%) | called by muse, varscan2
- TMSB4X | chrX:12975590 C>T | 5'Flank (SNP) | VAF 53/279 reads (19%) | catalogued as rs939978850, COSV66081290, COSV66081942; called by muse, mutect2, varscan2
- TNFSF4 | c.*145C>A | 3'UTR (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- TRAPPC10 | c.790+865T>C | Intron (SNP) | VAF 10/56 reads (18%) | called by muse, varscan2
- TTYH2 | c.1116+73G>A | Intron (SNP) | VAF 4/34 reads (12%) | catalogued as rs958172858; called by muse, mutect2
- USP51 | c.*1817A>G | 3'UTR (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
- WDR27 | c.784-100C>T | Intron (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2
- XKR6 | c.764+137784C>T | Intron (SNP) | VAF 57/371 reads (15%) | called by muse, mutect2, varscan2
- ZIC4 | c.688+1937G>A | Intron (SNP) | VAF 30/145 reads (21%) | called by muse, mutect2, varscan2
- ZNF75D | c.697-124T>C | Intron (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
